CCDI case PBCWKG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/1aeef04a-491e-451f-9196-bc95ae147c59

Demographics
Sex at birth: male.

Biospecimens (3 samples)
- Sample 0E1HEV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0E1HF7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E1HG6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
